Somatic mutation profile of tumor specimen 0DK844 from CCDI case PBBXZJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 12.7 years (4,624 days).
Specimen 0DK844: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ee69955-b8e3-4520-a012-c5536c731199.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK83V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e56cc890-bbf6-40fd-8d4f-61a50616fa0a

The open-access MAF lists 60 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 15, Intron 6, Nonsense Mutation 3, 3'UTR 2, 5'UTR 1, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALCR | c.1357G>A p.D453N (on ENST00000649521 / NM_001164737.2; = p.D437N on NM_001742.4) | Missense Mutation (SNP) | VAF 218/497 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs530931616, COSV64008410; called by muse, mutect2, varscan2
- CEP192 | c.7421A>G p.K2474R | Missense Mutation (SNP) | VAF 137/427 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs866276399, COSV58061480, COSV58072009; called by muse, mutect2, varscan2
- CLASRP | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs1568420694, COSV99673933; called by muse, mutect2, varscan2
- ERCC2 | c.1119-6C>T | Splice Region (SNP) | VAF 185/438 reads (42%) | catalogued as rs374636940; ClinVar: likely benign; called by muse, mutect2, varscan2
- ESRP1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 166/797 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs895123100; called by muse, mutect2, varscan2
- NTRK2 | c.1822G>A p.V608M (on ENST00000323115 / NM_001369534.1; = p.V624M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194954580, COSV52858767; called by muse, mutect2, varscan2
- PCDHB10 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99505055; called by muse, mutect2, varscan2
- PCDHB9 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs1186232513; called by muse, mutect2
- RPL22 | c.246T>G p.Y82* | Nonsense Mutation (SNP) | VAF 45/219 reads (21%) | catalogued as COSV52378666; called by muse, mutect2, varscan2
- TP53 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 98/138 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV53154091, COSV53788648; called by muse, mutect2, varscan2
- ZNF426 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.973); catalogued as rs753080226; called by muse, mutect2, varscan2
- ACVR2B | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 110/390 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ADGRD1 | c.791C>A p.T264K | Missense Mutation (SNP) | VAF 164/520 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by mutect2, varscan2
- ANKDD1B | c.674A>T p.N225I | Missense Mutation (SNP) | VAF 225/1227 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- BAIAP2L2 | c.1486C>A p.Q496K | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, varscan2
- BCOR | c.4202del p.P1401Rfs*83 (on ENST00000378444 / NM_001123385.2; = p.P1367Rfs*83 on NM_017745.6) | Frame Shift Del (DEL) | VAF 98/114 reads (86%) | called by mutect2, varscan2
- CELF2 | c.1478G>A p.R493H (on ENST00000416382 / NM_001025077.3; = p.R506H on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 303/720 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CTNNA2 | c.869A>T p.D290V | Missense Mutation (SNP) | VAF 50/1080 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- EIF3J | c.98C>G p.T33S | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERC1 | c.1304T>G p.F435C | Missense Mutation (SNP) | VAF 122/561 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAR2 | c.289_292dup p.M98Rfs*22 | Frame Shift Ins (INS) | VAF 166/630 reads (26%) | called by mutect2, varscan2
- GPR42 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 248/582 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.234); called by mutect2, varscan2
- GPRIN3 | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 125/442 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- ITPR1 | c.2449A>G p.I817V (on ENST00000354582; = p.I802V on NM_002222.7) | Missense Mutation (SNP) | VAF 116/502 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KLK6 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 97/451 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MORC4 | c.676A>G p.N226D | Missense Mutation (SNP) | VAF 173/217 reads (80%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MROH2B | c.4148T>C p.F1383S | Missense Mutation (SNP) | VAF 46/1128 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.202); called by muse, mutect2
- MYH6 | c.3238G>T p.E1080* | Nonsense Mutation (SNP) | VAF 44/374 reads (12%) | called by muse, mutect2, varscan2
- NT5C3B | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PCDHA9 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 92/766 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCDHGC5 | c.1865C>G p.S622C | Missense Mutation (SNP) | VAF 117/679 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PDE4B | c.1025T>G p.L342R | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POTED | c.1337T>G p.L446* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | called by mutect2, varscan2
- SIN3A | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTBN5 | c.5320G>T p.A1774S | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ZNF608 | c.3839G>A p.G1280D | Missense Mutation (SNP) | VAF 191/896 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL1 | c.2274C>T p.G758= (on ENST00000340736 / NM_001008701.3; = p.G753= on NM_014921.5) | Silent (SNP) | VAF 48/261 reads (18%) | catalogued as rs767845634; called by muse, mutect2, varscan2
- AHCYL1 | c.198G>A p.S66= | Silent (SNP) | VAF 127/661 reads (19%) | catalogued as rs141483929; called by muse, mutect2, varscan2
- ATP11A | c.663C>T p.P221= | Silent (SNP) | VAF 53/383 reads (14%) | catalogued as rs747735763; called by muse, mutect2, varscan2
- CCDC88C | c.3630G>A p.G1210= | Silent (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- COPA | c.2047C>T p.L683= | Silent (SNP) | VAF 230/852 reads (27%) | called by muse, mutect2, varscan2
- CPN2 | c.1377G>A p.P459= | Silent (SNP) | VAF 119/446 reads (27%) | catalogued as rs373278468; called by muse, mutect2, varscan2
- CTCFL | c.1362C>T p.S454= | Silent (SNP) | VAF 132/658 reads (20%) | catalogued as rs747047790; called by muse, mutect2, varscan2
- EZH2 | c.46C>A p.R16= | Silent (SNP) | VAF 199/568 reads (35%) | catalogued as COSV57448709; called by muse, mutect2, varscan2
- FAM209B | c.306T>C p.N102= | Silent (SNP) | VAF 137/752 reads (18%) | catalogued as COSV100990947; called by muse, mutect2, varscan2
- MXRA8 | c.699C>G p.A233= | Silent (SNP) | VAF 107/335 reads (32%) | called by muse, mutect2, varscan2
- PCDHGC5 | c.2175G>A p.G725= | Silent (SNP) | VAF 71/382 reads (19%) | catalogued as COSV52754524; called by muse, mutect2, varscan2
- S1PR2 | c.1011C>T p.G337= | Silent (SNP) | VAF 42/190 reads (22%) | called by mutect2, varscan2
- TOPAZ1 | c.1665A>T p.T555= | Silent (SNP) | VAF 169/590 reads (29%) | called by muse, mutect2, varscan2
- VPS51 | c.1381C>T p.L461= | Silent (SNP) | VAF 74/490 reads (15%) | called by muse, mutect2, varscan2
- ZFHX3 | c.6825C>A p.L2275= | Silent (SNP) | VAF 106/307 reads (35%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 14/435 reads (3%) | called by muse, mutect2
- CYP1A2 | c.*86A>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | catalogued as rs1249152270; called by muse, varscan2
- HOPX | c.-12-83G>A | Intron (SNP) | VAF 17/55 reads (31%) | catalogued as rs1281765806; called by muse, mutect2, varscan2
- OPALIN | c.-29C>T | 5'UTR (SNP) | VAF 90/269 reads (33%) | catalogued as rs778657175; called by muse, mutect2, varscan2
- PTBP1 | c.893-95G>A | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- SEL1L | c.2175+19T>C | Intron (SNP) | VAF 143/355 reads (40%) | called by muse, mutect2, varscan2
- SPRTN | c.718+11G>C | Intron (SNP) | VAF 127/522 reads (24%) | called by muse, mutect2, varscan2
- TECR | c.799+11C>T | Intron (SNP) | VAF 115/241 reads (48%) | catalogued as rs368695024; called by muse, mutect2, varscan2
- VAV1 | c.1778-58G>T | Intron (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
